Somatic mutation profile of tumor specimen TCGA-A2-A0YL-01A (aliquot TCGA-A2-A0YL-01A-21D-A10G-09) from TCGA case TCGA-A2-A0YL, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 48.5 years (17,702 days).
Specimen TCGA-A2-A0YL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d67c3d46-927a-49eb-ba5b-5691a75223ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A0YL-10A (Blood Derived Normal), aliquot TCGA-A2-A0YL-10A-01D-A10G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eea81c2d-ad24-4bec-bf61-5beee62c8fb4

The open-access MAF lists 34 somatic variants for this specimen: 21 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 11, Nonsense Mutation 6, Intron 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.1660C>T p.Q554* | Nonsense Mutation (SNP) | VAF 12/152 reads (8%) | catalogued as rs953440640, CM143325, COSV62199089, COSV62210187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- NF1 | c.3144G>A p.W1048* | Nonsense Mutation (SNP) | VAF 14/124 reads (11%) | catalogued as rs1555614635, CM143361, COSV100648000, COSV62211532; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 17/121 reads (14%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANKS1B | c.814C>G p.Q272E | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100247352; called by muse, mutect2
- BRCC3 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 6/188 reads (3%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.138); catalogued as COSV100341745; called by muse, mutect2
- CDC27 | c.1160C>A p.S387Y | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV99296033; called by muse, mutect2
- EIF5 | c.39C>G p.F13L | Missense Mutation (SNP) | VAF 6/165 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.558); catalogued as COSV53685860, COSV99384982; called by muse, mutect2
- EIF5 | c.238C>T p.H80Y | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.277); catalogued as COSV53686759; called by muse, mutect2, varscan2
- ETNK2 | c.1029C>G p.F343L | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV65820132; called by muse, mutect2
- HSD17B10 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV51448818; called by muse, mutect2, varscan2
- ILK | c.903G>A p.M301I | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54992541; called by muse, mutect2, varscan2
- LMTK3 | c.4369C>A p.P1457T | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated, low confidence (0.43); PolyPhen probably damaging (0.981); catalogued as COSV99541062; called by muse, mutect2, varscan2
- MAP2 | c.4772C>G p.S1591* | Nonsense Mutation (SNP) | VAF 12/121 reads (10%) | catalogued as COSV52307121; called by muse, mutect2, varscan2
- MSX2 | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 10/63 reads (16%) | catalogued as COSV53328259; called by muse, mutect2, varscan2
- NCOR1 | c.3577G>T p.E1193* | Nonsense Mutation (SNP) | VAF 11/157 reads (7%) | catalogued as COSV99251581; called by muse, mutect2
- RANBP6 | c.2212C>G p.L738V | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99424340; called by muse, mutect2
- SEC61A1 | c.729G>A p.M243I | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99684981; called by muse, mutect2
- SGSM2 | c.1867G>A p.E623K (on ENST00000426855 / NM_001098509.2; = p.E668K on NM_014853.3) | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.846); catalogued as rs755724967, COSV99280447; called by muse, mutect2, varscan2
- TTLL1 | c.1204C>G p.Q402E | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.01); catalogued as COSV56740497; called by mutect2, varscan2
- CDH1 | c.1090_1100del p.T364Hfs*4 | Frame Shift Del (DEL) | VAF 22/121 reads (18%) | called by mutect2, pindel, varscan2
- PXMP2 | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2
- CABIN1 | c.6309C>T p.A2103= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV54088717; called by muse, mutect2, varscan2
- CPSF4 | c.798C>T p.L266= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as COSV99461858; called by muse, mutect2
- ERICH3 | c.3546G>A p.L1182= | Silent (SNP) | VAF 9/132 reads (7%) | catalogued as COSV100445342; called by muse, mutect2
- FAM50A | c.393C>T p.G131= | Silent (SNP) | VAF 22/125 reads (18%) | catalogued as rs1474013036, COSV50133034; called by muse, mutect2, varscan2
- GABRE | c.672C>T p.I224= | Silent (SNP) | VAF 20/198 reads (10%) | catalogued as COSV64821248; called by muse, mutect2
- LAMB1 | c.1422C>T p.S474= | Silent (SNP) | VAF 7/86 reads (8%) | catalogued as rs780369106, COSV99741525; called by muse, mutect2
- MUC5B | c.14469C>G p.T4823= | Silent (SNP) | VAF 14/166 reads (8%) | catalogued as rs746355285, COSV101500653; called by muse, mutect2
- OBSL1 | c.2292G>A p.V764= | Silent (SNP) | VAF 16/198 reads (8%) | catalogued as rs561384957, COSV99217352; called by muse, mutect2
- RGS7 | c.879C>T p.Y293= | Silent (SNP) | VAF 49/168 reads (29%) | catalogued as rs1198113819, COSV58559908; called by muse, mutect2, varscan2
- TDRD6 | c.1476G>A p.Q492= | Silent (SNP) | VAF 5/96 reads (5%) | catalogued as COSV100288159; called by muse, mutect2
- TRPM2 | c.2973C>T p.F991= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV55976470; called by muse, mutect2, varscan2
- FAM104A | c.322-2945G>C | Intron (SNP) | VAF 22/315 reads (7%) | catalogued as COSV100245434; called by muse, mutect2
- RPL23 | c.97+47A>G | Intron (SNP) | VAF 4/28 reads (14%) | catalogued as rs182421097; called by mutect2, varscan2
